Somatic mutation profile of tumor specimen TCGA-S9-A6U2-01A (aliquot TCGA-S9-A6U2-01A-21D-A33T-08) from TCGA case TCGA-S9-A6U2, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 48.7 years (17,800 days).
Specimen TCGA-S9-A6U2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7b80234-e5f3-4d8d-a661-3a9df6894009.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-S9-A6U2-10A (Blood Derived Normal), aliquot TCGA-S9-A6U2-10A-01D-A33W-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3f19f73-d65c-4559-8ac8-d8abadb75343

The open-access MAF lists 30 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 6, Nonsense Mutation 2, Splice Site 1, Intron 1, Splice Region 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.601C>T p.R201W | Missense Mutation (SNP) | VAF 64/111 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1157030312, COSV50547633; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 59/182 reads (32%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PIK3CA | c.316G>A p.G106S | Missense Mutation (SNP) | VAF 85/214 reads (40%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV55878215, COSV55881107, COSV55917331; called by muse, mutect2, varscan2
- ARHGEF9 | c.1460C>A p.A487D | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.027); catalogued as COSV99491355; called by muse, mutect2, varscan2
- DNAH8 | c.3309T>A p.N1103K | Missense Mutation (SNP) | VAF 63/179 reads (35%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100543273; called by muse, mutect2, varscan2
- EHMT2 | c.3542C>T p.A1181V | Missense Mutation (SNP) | VAF 45/114 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.04); catalogued as COSV99998588; called by muse, mutect2, varscan2
- ENGASE | c.1038G>A p.K346= | Splice Region (SNP) | VAF 66/168 reads (39%) | catalogued as COSV100285650; called by muse, mutect2, varscan2
- FER1L6 | c.3575G>A p.R1192Q | Missense Mutation (SNP) | VAF 181/447 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.47); catalogued as rs369018172; called by muse, mutect2, varscan2
- FLG | c.6442G>A p.G2148R | Missense Mutation (SNP) | VAF 326/1222 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as rs1405608508, COSV100910497; called by muse, mutect2
- HIVEP1 | c.6514C>T p.R2172* | Nonsense Mutation (SNP) | VAF 85/242 reads (35%) | catalogued as rs750361782, COSV65101189; called by muse, mutect2, varscan2
- KMT2D | c.15028G>A p.A5010T | Missense Mutation (SNP) | VAF 48/143 reads (34%) | SIFT tolerated (0.31); PolyPhen benign (0.376); catalogued as COSV99977479; called by muse, mutect2, varscan2
- KRT6B | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 111/304 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.149); catalogued as rs142625176, COSV99360411, COSV99360834; called by muse, varscan2
- OR5J2 | c.611G>A p.G204E | Missense Mutation (SNP) | VAF 17/264 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100398897, COSV100399206; called by muse, mutect2
- RAD21 | c.1100G>T p.G367V | Missense Mutation (SNP) | VAF 85/199 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99814781; called by muse, mutect2, varscan2
- SLC52A3 | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 38/120 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs774918391, COSV54078088, COSV54078341; called by muse, mutect2, varscan2
- STPG4 | c.70A>G p.I24V | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as COSV99681192; called by muse, mutect2
- SUN3 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 20/228 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779108714, COSV99813821; called by muse, mutect2
- TCN1 | c.1261C>T p.R421C | Missense Mutation (SNP) | VAF 28/440 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs978503152, COSV57252625, COSV57254628; called by muse, mutect2
- TRPM8 | c.3130+1G>C p.X1044_splice | Splice Site (SNP) | VAF 42/134 reads (31%) | catalogued as COSV61220750, COSV61222625; called by muse, mutect2, varscan2
- ZFPM2 | c.1976A>G p.N659S | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV65876522; called by muse, mutect2, varscan2
- ZNF800 | c.1493A>G p.K498R | Missense Mutation (SNP) | VAF 78/195 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.096); catalogued as rs780726907, COSV99757640; called by muse, mutect2, varscan2
- TCF12 | c.1725_1729delinsCT p.E575_E577delinsD* | Nonsense Mutation (DEL) | VAF 26/54 reads (48%) | called by pindel, varscan2*
- BCR | c.3621T>C p.F1207= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV100005952; called by muse, mutect2, varscan2
- IL1RL1 | c.1110T>C p.T370= | Silent (SNP) | VAF 6/118 reads (5%) | catalogued as COSV52111835, COSV99293582; called by muse, mutect2
- KIF26A | c.4047G>A p.K1349= | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as rs894013924, COSV100180742; called by muse, mutect2, varscan2
- POLA2 | c.1068G>A p.T356= | Silent (SNP) | VAF 56/126 reads (44%) | catalogued as rs747786814, COSV99640609; called by muse, mutect2, varscan2
- STX11 | c.252C>T p.R84= | Silent (SNP) | VAF 24/57 reads (42%) | catalogued as COSV62448394; called by muse, mutect2, varscan2
- SUPT3H | c.195G>A p.V65= (on ENST00000371460 / NM_181356.3; = p.V54= on NM_003599.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 53/197 reads (27%) | catalogued as rs1179862963, COSV100176145; called by muse, mutect2, varscan2
- COL4A1 | c.615+149C>T | Intron (SNP) | VAF 36/101 reads (36%) | catalogued as rs534825220; called by muse, mutect2, varscan2
- ZC4H2 | c.-1T>C | 5'UTR (SNP) | VAF 46/192 reads (24%) | catalogued as COSV100564727; called by muse, mutect2, varscan2
